Surgical pathology report (de-identified scan), TCGA case TCGA-64-5775, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5775-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Clinical History/Diagnosis: Lung CA. Malignant Pleural Effusion.

[REDACTED]

Source of Specimen(s):

- 1: Speciment sent to Microbiology
- 2: Speciment sent to Microbiology
- 3: Speciment sent to Microbiology
- 4: Pleural tissue
- 5: Speciment sent to Microbiology
- 6: Speciment sent to Microbiology
- 7: Speciment sent to Microbiology
- 8: Fistula, chest wall
- 9: Fistula, chest wall left
- 10: Pleura left chest

TCGA-64-5775

Gross Description:

Received in ten parts.

Source of Tissue: 1. Microbiology Specimen

Source of Tissue: 2. Microbiology Specimen

Source of Tissue: 3. Microbiology Specimen

Source of Tissue: 4. Labeled #4, "pleural tissue"

Frozen Section Diagnosis: 4FS- HIGH GRADE NEOPLASM AS DISCUSSED PER

[REDACTED]

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "pleural tissue" are 6.5 x 4.5 x 1.2 cm of tan to tan-pink rubbery firm tissue fragments.

Representative sections are submitted for frozen section evaluation and the frozen section residue is submitted in one block. Additional representative sections are submitted in three blocks.

Designation of Sections: 4FS, 4A-4C

Source of Tissue: 5. Microbiology Specimen

Source of Tissue: 6. Microbiology Specimen

Source of Tissue: 7. Microbiology Specimen

Source of Tissue: 8. Labeled #8, "chest wall fistula"

Frozen Section Diagnosis: 8FS- HIGH GRADE NEOPLASM PER [REDACTED]

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "chest wall fistula" is a 1.5 x 1.0 cm tan rubbery firm tissue fragment. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 8FS

Source of Tissue: 9. Labeled #9, "left chest wall fistula"

Gross Description: Received fresh with patient name and medical record number labeled "left chest wall fistula" is a 8.5 x 3.0 cm light-tan skin

[page 2 of 2]
ellipse excised to a depth of 2.6 cm. There are two tan raised lesions on the skin surface, 2.0 cm in greatest dimension. These are sectioned to reveal two fistulous tracts containing tan to pink-red soft material. Representative sections are submitted in three blocks.

Designation of Sections: 9A-9B- fistula tract, 9C- soft tissue

TCGA-64-5775

Source of Tissue: 10. Labeled #10, "pleura left chest"

Gross Description: Received fresh with patient name and medical record number labeled "pleura left chest" are 24.0 x 15.0 x 3.0 cm of tan to pink-red irregular fragments of soft tissue and clotted blood.

Representative sections are submitted in four blocks.

Designation of Sections: 10A-10D

Final Diagnosis:

1, 2, 3. Cultures

4. Pleural tissue: ✓
- Adenocarcinoma.

5, 6, 7. Cultures

8. Chest wall fistula: ✓
- Adenocarcinoma invading chest wall.

9. Chest wall fistula, left: ✓
- Adenocarcinoma invading chest wall and skin with ulceration, extending to the circumferential margin and deep tissue free wall.

10. Pleural left chest: J
- Adenocarcinoma.

Comment: The tumor is positive for CK7, TTF-1, Cam 5.2, cytokeratin AE1/AE3, and vimentin; and negative for MA903, CK20, CD31, CD34, CD45, CD20, Calretinin, EMA, Melan A, HMB-45, and S-100 protein. These findings support the diagnosis of a primary lung adenocarcinoma.

pTNM: T4 N0 Mx.

Source: NCI Genomic Data Commons file 0f1a8df0-57fe-4a8a-bd45-2e53205344c7 (TCGA-64-5775.EB576E3D-FA59-42B7-AF77-416013A9BC90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).